Somatic mutation profile of tumor specimen TCGA-D7-8579-01A (aliquot TCGA-D7-8579-01A-11D-2340-08) from TCGA case TCGA-D7-8579, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 66.0 years (24,120 days).
Specimen TCGA-D7-8579-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9278f168-6983-4da5-a0c5-8e81ea746bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-8579-10A (Blood Derived Normal), aliquot TCGA-D7-8579-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f39fa1-9790-4ea6-9476-ca5de39291c2

The open-access MAF lists 115 somatic variants for this specimen: 85 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 28, Nonsense Mutation 3, RNA 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 29/181 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2, varscan2
- AC004832.3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs768377155, COSV56741984; called by muse, mutect2, varscan2
- ADCY2 | c.2804T>G p.V935G | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57882078; called by muse, mutect2, varscan2
- ADGRF2 | c.1466T>G p.V489G (on ENST00000296862 / NM_001368115.2; = p.V421G on NM_153839.7) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57290958; called by muse, mutect2
- AKR1C1 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV66499413; called by muse, mutect2
- ANO4 | c.1441C>T p.R481W (on ENST00000392977 / NM_001286615.2; = p.R446W on NM_178826.4) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765804915, COSV54602170; called by muse, mutect2, varscan2
- ARHGEF17 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746119368, COSV55234304; called by muse, mutect2, varscan2
- ARID1A | c.4069C>T p.Q1357* | Nonsense Mutation (SNP) | VAF 33/350 reads (9%) | catalogued as COSV61381574; called by muse, mutect2, varscan2
- BRINP2 | c.1966A>G p.S656G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV64178486; called by muse, mutect2, varscan2
- BTBD8 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV61546910; called by muse, mutect2, varscan2
- CACNA1E | c.4411G>A p.V1471M | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs915291484, COSV62385122; called by muse, mutect2, varscan2
- CCDC172 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV100319614; called by muse, mutect2, varscan2
- CCDC186 | c.792A>C p.E264D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV65161542; called by muse, mutect2, varscan2
- CFAP54 | c.8186A>C p.N2729T | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV61573071; called by muse, mutect2, varscan2
- CUL7 | c.553A>C p.I185L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54819058; called by muse, mutect2, varscan2
- CYLC1 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148140928, COSV100255030, COSV61413473; called by muse, mutect2, varscan2
- CYP7A1 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV56964394; called by muse, mutect2, varscan2
- DCLK1 | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV55194670; called by muse, mutect2, varscan2
- DGKI | c.2056T>G p.L686V | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV55959059; called by muse, mutect2, varscan2
- DNAH11 | c.2845A>T p.I949F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs763972586, COSV60964510; called by muse, mutect2, varscan2
- DNAH11 | c.4259A>C p.K1420T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV60964522; called by muse, mutect2, varscan2
- EGR4 | c.1486C>T p.R496C (on ENST00000545030; = p.R393C on NM_001965.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71532151; called by muse, mutect2
- ERICH3 | c.2737T>G p.L913V | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV100446188, COSV58610781; called by muse, mutect2, varscan2
- FAM47C | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1556332457, COSV63725336; called by muse, mutect2, varscan2
- FANCB | c.1618T>G p.L540V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs144205393, COSV60760697; called by muse, mutect2, varscan2
- FCRL3 | c.380A>C p.N127T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1412324567, COSV63842054; called by muse, mutect2, varscan2
- FLG | c.6562A>C p.S2188R | Missense Mutation (SNP) | VAF 82/620 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs759067455, COSV64236556, COSV64241700, COSV64244453; called by muse, mutect2, varscan2
- FZD1 | c.1862T>A p.I621N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55311904; called by muse, mutect2, varscan2
- GLI3 | c.2864C>T p.T955M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767298749, COSV67886413; called by muse, mutect2, varscan2
- GRAMD1A | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765331104, COSV58767703; called by muse, mutect2
- GRM5 | c.3632C>T p.S1211L (on ENST00000305447 / NM_001143831.2; = p.S1179L on NM_000842.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV59612986; called by muse, mutect2, varscan2
- H1-3 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV55097915; called by muse, mutect2, varscan2
- H2BW1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556337689, COSV54220625; called by muse, mutect2, varscan2
- HS3ST5 | c.996T>A p.N332K | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57135760; called by muse, mutect2
- KCNMB2 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV64201354, COSV64201489; called by muse, mutect2, varscan2
- KIAA1210 | c.2279A>C p.K760T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV68178098; called by muse, mutect2, varscan2
- KIR2DL4 | c.1018G>A p.A340T (on ENST00000396284; = p.A266T on NM_001080770.2) | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as rs763530813, COSV58495097; called by muse, mutect2, varscan2
- KLB | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs138571801; called by muse, mutect2, varscan2
- LAMA1 | c.7868T>C p.L2623P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140908333; called by mutect2, varscan2
- LPA | c.5502A>C p.Q1834H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1010151909, COSV60298048, COSV60302164, COSV60303870; called by muse, mutect2, varscan2
- LRFN5 | c.327C>A p.N109K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53258484; called by muse, mutect2, varscan2
- MNT | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs1225520687, COSV51512906; called by muse, mutect2
- MYO16 | c.2906A>C p.K969T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV51785164; called by muse, mutect2, varscan2
- MYO3A | c.3630A>C p.E1210D | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV56337265, COSV56346975; called by muse, mutect2, varscan2
- OR10R2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV63769053; called by muse, mutect2, varscan2
- OR5M8 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV59117341; called by muse, mutect2, varscan2
- OR8B4 | c.216T>G p.C72W | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as COSV100635745; called by muse, mutect2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- PAPPA | c.1286A>G p.N429S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60286031; called by muse, mutect2, varscan2
- PCDHA12 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs782472866, COSV99164890; called by muse, mutect2, varscan2
- PCDHB8 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 27/621 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.734); catalogued as rs868969986, COSV50784405; called by muse, mutect2
- PCLO | c.13080A>C p.E4360D | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61646185; called by muse, mutect2, varscan2
- PLXDC2 | c.898A>C p.T300P | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65905740; called by muse, mutect2, varscan2
- PRLHR | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53304344; called by muse, mutect2, varscan2
- PTPRD | c.3379C>A p.Q1127K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1349731798, COSV100642663; called by muse, mutect2
- RAG2 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100271518, COSV57558399; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2
- RNF6 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.291); catalogued as rs769463455, COSV60419494; called by muse, mutect2
- RPS6KC1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as COSV65300817; called by muse, mutect2, varscan2
- SEC31B | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.751); catalogued as COSV100947398, COSV64844880; called by muse, mutect2, varscan2
- SELP | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1036688172, COSV55254109; called by muse, mutect2, varscan2
- SERPINA9 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs760573855, COSV54076068; called by muse, mutect2, varscan2
- SLC43A3 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140882001; called by muse, mutect2, varscan2
- SLIT1 | c.3089A>G p.Q1030R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs753416251, COSV56592405; called by mutect2, varscan2
- SRRM2 | c.3218G>A p.S1073N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV57076048; called by muse, mutect2, varscan2
- STAM2 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55732410; called by muse, mutect2, varscan2
- SYN3 | c.481T>C p.F161L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60511049; called by muse, mutect2, varscan2
- TAS1R2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs370587266; called by muse, mutect2, varscan2
- TFEC | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.183); catalogued as COSV55403002; called by muse, mutect2, varscan2
- TMEM144 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV56701744; called by muse, mutect2, varscan2
- TNFAIP3 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as COSV52800057; called by muse, mutect2, varscan2
- TRIM5 | c.425T>A p.L142H | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59900707; called by muse, mutect2
- USP9X | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61065718; called by muse, mutect2, varscan2
- UVSSA | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs749450224, COSV66230216; called by muse, mutect2
- WDR44 | c.2423A>C p.K808T | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54163516, COSV54165432; called by muse, mutect2, varscan2
- WEE2 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs905047580, COSV66878110; called by muse, mutect2
- ZFP82 | c.990A>C p.K330N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV101088794; called by muse, varscan2
- ZNF274 | c.1352G>A p.R451H (on ENST00000610905; = p.R346H on NM_016324.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.029); catalogued as rs746571956, COSV58763221; called by muse, mutect2, varscan2
- ZNF667 | c.314A>G p.Q105R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV52636298; called by muse, mutect2
- ZNF675 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV63096515; called by muse, mutect2, varscan2
- ZNF804A | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV56452654, COSV56456436; called by muse, mutect2
- HNF1A | c.1829dup p.L611Afs*38 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2
- RTEL1 | c.3140C>G p.S1047C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2
- RYR2 | c.7906G>T p.E2636* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- ADAMTS16 | c.2445T>G p.T815= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV56976480, COSV56976826; called by muse, mutect2, varscan2
- AKAP12 | c.3084C>T p.G1028= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs1434035188, COSV53577627; called by muse, mutect2, varscan2
- ARMC7 | c.390C>G p.R130= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV55461174; called by muse, mutect2, varscan2
- CD160 | c.444C>T p.H148= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV52523758; called by muse, mutect2, varscan2
- CEP85 | c.42C>T p.H14= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs201779964, COSV53330676; called by muse, mutect2, varscan2
- CLDN17 | c.631A>C p.R211= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV54522551; called by muse, mutect2
- CUL7 | c.267C>T p.I89= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs201158458; called by muse, mutect2, varscan2
- DCAF12L2 | c.1290G>A p.A430= | Silent (SNP) | VAF 47/283 reads (17%) | catalogued as rs763096279, COSV63581315, COSV63582525; called by muse, mutect2, varscan2
- DIO2 | c.627A>C p.R209= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as COSV101375811, COSV70445575, COSV70446068; called by muse, mutect2
- E2F2 | c.1287C>T p.Y429= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs146034018; called by muse, mutect2, varscan2
- GAB3 | c.1506C>T p.D502= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs782473076, COSV65819204; called by muse, mutect2
- LRRC37A2 | c.3876G>A p.T1292= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs368573638; called by muse, mutect2
- MFSD6L | c.1500C>T p.Y500= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs749850262, COSV61688333; called by muse, mutect2, varscan2
- NPAP1 | c.2070A>T p.S690= | Silent (SNP) | VAF 20/241 reads (8%) | catalogued as COSV61508530; called by muse, mutect2
- NPC1L1 | c.336C>T p.R112= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV56926866; called by muse, mutect2, varscan2
- OR1A1 | c.855T>G p.P285= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV58404118; called by muse, mutect2, varscan2
- OR4C12 | c.858A>G p.T286= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV58860423; called by muse, mutect2
- OR5L2 | c.642C>A p.I214= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV65723779; called by muse, mutect2, varscan2
- PCDH17 | c.1641T>C p.A547= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV64975893; called by muse, mutect2, varscan2
- PLXNA2 | c.585C>T p.F195= | Silent (SNP) | VAF 34/272 reads (13%) | catalogued as COSV65442156; called by muse, mutect2, varscan2
- PRAMEF19 | c.903T>G p.T301= | Silent (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- RIMBP2 | c.429C>T p.S143= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs765478893, COSV55469143; called by muse, mutect2
- RPP38 | c.726T>G p.P242= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as rs1185868788, COSV65382505; called by muse, mutect2
- STAMBP | c.936C>T p.N312= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1366496234, COSV59897737; called by muse, mutect2, varscan2
- SYNE1 | c.5838T>G p.T1946= (on ENST00000367255 / NM_182961.4; = p.T1953= on NM_033071.3) | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV54934821; called by muse, mutect2, varscan2
- SYNE1 | c.2319T>C p.I773= (on ENST00000367255 / NM_182961.4; = p.I780= on NM_033071.3) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV55024256; called by muse, mutect2, varscan2
- SYT4 | c.960C>G p.S320= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV54901723, COSV99674627; called by muse, mutect2, varscan2
- UNC5C | c.1069T>C p.L357= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs992187023, COSV71660878; called by muse, mutect2, varscan2
- DCHS2 | n.7294T>C | RNA (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100600914; called by muse, mutect2, varscan2
- SNORD116-15 | n.44A>C | RNA (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
